Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A7Q1, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A7Q1-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Lymph node is located in intra-abdominal and enlarged with 3x3x3cm in size, soft, yellowish and gray surface.

Microscopic Description: Tumor architectures are replaced by diffuse pattern or cords or sheets intermixing in fat tissue. The tumor cells are composed of small and large transformed lymphoid cells with irregular hyperchromatic nuclei. Tumor cells are oval or round in shape with scant cytoplasm. Nucleoli is single or multiple. Mitotic figures are common.

Diagnosis Details: Malignant lymphoma, large B cell, diffuse type.

Comments:

Formatted Path Reports: Tumor site: Lymph node, intra-abdominal

Tumor size (in cm): 3 x 3 x 3cm

Histologic type: Diffuse large b-cell lymphoma

Histologic grade: Poorly differentiated

Tumor extent:

Lymph nodes:

Margins:

Evidence of neo-adjuvant treatment:

If yes, type of treatment seen:

Severity of treatment effect:

Comments: CD20(+), CD3(-)

ICD-O-3
Lymphoma, diffuse large B cell
C64
Site Mesentery
path 481
Intra abdominal lymph node
C77.2
QW 9/26/13

Source: NCI Genomic Data Commons file 0e12cc5a-4945-4a35-a768-c850b4bbf90d (TCGA-FA-A7Q1.D9C18E71-3D93-4B22-87B7-E5C34CC670C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).